Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACJ1, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACJ1-TTP1-A (Primary Tumor).

Submissions:

- A) left lung, neoplasm lower lobe, fine needle aspiration
- B) left lung, lower lobe, removal
- C) inferior pulmonary ligament left lymph node, removal
- D) subcarinal left lymph node, removal
- E) lymph node of left pulmonary hilum, removal
- F) subcarinal lymph nodes, removal

CDDP-YP-ACJ1-01-PR

**Macroscopic report:**

- A) a few cc of blood serum material
- B) lung lobe of cm 13x10x3 with visceral pleura retracted in correspondence, to the cut, the neoplasm of parenchymal cm 4.3 in major axis, with polycyclic margins, that is 3 cm from bronchial resection margin.
- Remaining parenchyma of congested and edematous appearance. Isolate 2 peribronchial lymph nodes.

B1-B3 neoplasm

B4 bronchial margin

B5 parenchyma random

B6-B7 peri-bronchial lymph nodes

C) lymph node fragments, the eldest of 1.5 cm

D) one lymph node of 1.1 cm in major axis

E) lymph node fragments, the eldest of 1 cm

F) lymph node fragments, the eldest of 1.2 cm

Diagnosis:

A,B) Poorly differentiated lung adenocarcinoma (G3), necrotic, focally infiltrating the visceral pleura.

No evidence of peritumoral neoplastic invasion of vessels.

Margins of bronchial and vascular surgical resection are free of cancer.

Edema of the remaining lung parenchyma.

unspecified reactive lymphadenitis with sinus histiocytosis and anthracosis in 2/2 lymph nodes.

C) lymph- perinodal lymph metastatic of adenocarcinoma

D,E,F) unspecified reactive lymphadenitis with sinus histiocytosis and anthracosis in 3/3 lymph nodes.

Histopathologic staging:

pT2;N2

Extemporaneous examination:

A)Positive finding CTM, non-small cell

Staging Discrepancy		/

ICD-0-3

adenocarcinoma, NOS 8140/3
Site: (L) lung, lower lobe C34.3

ICD-10

C34.32

lu
12/16/16

Source: NCI Genomic Data Commons file 5004680a-3ea6-4e48-a375-cf48bc08608d (CDDP-ACJ1-TTP1.0B445D48-55B9-434F-A5FD-4C4458D1FC1A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).